Somatic mutation profile of tumor specimen MP2PRT-PAUFJB-TMP1-A (aliquot MP2PRT-PAUFJB-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUFJB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (963 days).
Specimen MP2PRT-PAUFJB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8294664b-7491-4883-807a-4df7303a1659.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUFJB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUFJB-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d06403b-a20a-4902-9fa8-0f8eb25dba94

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAR1 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 175/428 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs777258321; called by muse, mutect2, varscan2
- KALRN | c.8861G>A p.R2954H (on ENST00000360013 / NM_001024660.4; = p.R1257H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/243 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1559891981, COSV52249201; called by muse, mutect2, varscan2
- PARP12 | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 139/275 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs1156441603, COSV54933248; called by muse, mutect2, varscan2
- H3C12 | c.153G>C p.E51D | Missense Mutation (SNP) | VAF 162/360 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- LDLRAD4 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 27/291 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OBP2B | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.023); called by muse, mutect2
- PTPRJ | c.1900G>T p.V634L | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.05); called by muse, mutect2
- STK32B | c.503_504insAGGACTCGGTTC p.A168_T169insGLGS | In Frame Ins (INS) | VAF 56/218 reads (26%) | called by pindel, varscan2
- STK32B | c.508G>T p.V170L | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, varscan2
- KCNC2 | c.168G>A p.P56= | Silent (SNP) | VAF 38/560 reads (7%) | catalogued as COSV54365858; called by muse, mutect2
- SEMA6A | c.2844C>T p.S948= | Silent (SNP) | VAF 143/341 reads (42%) | catalogued as COSV56711806, COSV99145623; called by muse, mutect2, varscan2
- SLC22A7 | c.1188G>A p.S396= (on ENST00000372585 / NM_153320.2; = p.S394= on NM_006672.3) | Silent (SNP) | VAF 148/297 reads (50%) | catalogued as rs373090700; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406872 ins ACCC | 3'Flank (INS) | VAF 6/72 reads (8%) | called by mutect2, pindel
